Somatic mutation profile of tumor specimen TCGA-BP-5168-01A (aliquot TCGA-BP-5168-01A-01D-1421-08) from TCGA case TCGA-BP-5168, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.8 years (27,692 days).
Specimen TCGA-BP-5168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82b0dcfd-64b6-4bff-9878-27d944ed961d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5168-11A (Solid Tissue Normal), aliquot TCGA-BP-5168-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1790206f-8536-4e1a-ab74-face3a4e7aba

The open-access MAF lists 127 somatic variants for this specimen: 95 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 31, Frame Shift Del 13, Nonsense Mutation 3, In Frame Del 3, Splice Site 3, Frame Shift Ins 2, Translation Start Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60679996; called by muse, mutect2, varscan2
- ABCG5 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV53211470; called by muse, mutect2, varscan2
- ACAD10 | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV58158499; called by muse, mutect2, varscan2
- ACO1 | c.1342G>C p.G448R | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59379776, COSV59380867; called by muse, mutect2, varscan2
- ADAMTS13 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs782814321, COSV63021763; called by muse, mutect2, varscan2
- ARHGAP6 | c.1109T>A p.L370H | Missense Mutation (SNP) | VAF 153/249 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57297527; called by muse, mutect2, varscan2
- ASB1 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52827201; called by muse, mutect2, varscan2
- B3GNT6 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1438590185, COSV62828502; called by muse, mutect2, varscan2
- BMP6 | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV51666892; called by muse, mutect2, varscan2
- CADM2 | c.91A>G p.N31D (on ENST00000407528 / NM_001167674.2; = p.N33D on NM_153184.4) | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV67381654; called by muse, mutect2, varscan2
- CAPZA2 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV63266879; called by muse, mutect2, varscan2
- CENPF | c.8749A>T p.T2917S | Missense Mutation (SNP) | VAF 11/328 reads (3%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as COSV65275790; called by muse, mutect2
- CHI3L1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 66/251 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV55138524; called by muse, mutect2, varscan2
- CLEC12A | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58561545; called by muse, varscan2
- CLEC12A | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV58561553; called by muse, varscan2
- COL4A1 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.766); catalogued as COSV65427356; called by muse, mutect2, varscan2
- COLEC10 | c.220+1G>A p.X74_splice | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as rs1437708860, COSV60521648; called by muse, mutect2
- CSF2RA | c.973G>C p.V325L | Missense Mutation (SNP) | VAF 274/759 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV62625154; called by muse, mutect2, varscan2
- CSMD1 | c.3991del p.D1331Tfs*16 (on ENST00000520002; = p.D1330Tfs*16 on NM_033225.6) | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as COSV59331580; called by mutect2, pindel, varscan2
- EDC4 | c.1258T>C p.Y420H | Missense Mutation (SNP) | VAF 132/418 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV62766429; called by muse, mutect2, varscan2
- EPS8L2 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV59348297; called by muse, mutect2, varscan2
- FPGS | c.1425C>G p.N475K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV61227765; called by muse, mutect2, varscan2
- GDAP1L1 | c.96C>G p.D32E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV61157620; called by muse, varscan2
- HMCN1 | c.16394A>T p.H5465L | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54909037; called by muse, mutect2, varscan2
- HPS6 | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV54625921; called by muse, mutect2, varscan2
- IDE | c.217A>T p.I73F | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs776980415, COSV56424425; called by muse, mutect2, varscan2
- IDI2 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV52988303, COSV52988465; called by muse, mutect2, varscan2
- KHK | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as COSV53150323; called by muse, mutect2, varscan2
- LPCAT3 | c.1381T>A p.F461I | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.122); catalogued as rs781810040, COSV54642382; called by muse, mutect2, varscan2
- MAML1 | c.1297A>T p.T433S | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV52986365; called by muse, mutect2, varscan2
- MFAP3L | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64372342; called by muse, mutect2, varscan2
- MROH5 | c.3672C>G p.C1224W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV61472124, COSV61472588; called by muse, mutect2, varscan2
- MSL1 | c.1370T>A p.V457E (on ENST00000398532 / NM_001365919.1; = p.V194E on NM_001012241.2) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59899403; called by muse, mutect2, varscan2
- MYBPC1 | c.2609A>T p.E870V (on ENST00000550270 / NM_206820.2; = p.E877V on NM_002465.4) | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.673); catalogued as COSV62253887; called by muse, mutect2, varscan2
- NCAPH | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV53636933; called by muse, mutect2, varscan2
- NKX2-2 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65819788; called by muse, mutect2, varscan2
- NPNT | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59754675; called by muse, mutect2
- OBSCN | c.13715G>T p.C4572F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52785282; called by muse, mutect2, varscan2
- OR1B1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59171881; called by muse, mutect2, varscan2
- OR51A2 | c.837T>G p.N279K | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.395); catalogued as COSV100985107, COSV66748499; called by muse, mutect2, varscan2
- OTUD6B | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53443144; called by muse, mutect2, varscan2
- PACS2 | c.950C>G p.P317R | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57653987; called by muse, mutect2, varscan2
- PCDHB13 | c.2375A>G p.N792S | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53397698; called by muse, mutect2, varscan2
- PITHD1 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 31/122 reads (25%) | catalogued as COSV55755205; called by muse, mutect2, varscan2
- PLAT | c.1489C>G p.R497G | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs538933951, COSV54276245; called by muse, mutect2, varscan2
- PTPRN2 | c.381-1G>A p.X127_splice | Splice Site (SNP) | VAF 34/149 reads (23%) | catalogued as COSV67043462; called by muse, mutect2, varscan2
- RBAK | c.1279A>G p.K427E | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62331717; called by muse, mutect2, varscan2
- RFLNA | c.410C>T p.T137I (on ENST00000546355 / NM_001365156.1; = p.T56I on NM_181709.4) | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58038272; called by muse, mutect2, varscan2
- RPH3A | c.224G>A p.R75Q (on ENST00000389385 / NM_001143854.2; = p.R71Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772886838, COSV66991177; called by muse, mutect2, varscan2
- RPN2 | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.951); catalogued as COSV52906625; called by muse, mutect2
- RRM2 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58817010; called by muse, mutect2, varscan2
- SACS | c.8833C>A p.Q2945K | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.438); catalogued as COSV66541713; called by muse, mutect2, varscan2
- SCAF11 | c.1018A>T p.I340L | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV65477152; called by muse, varscan2
- SCRIB | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746150496, COSV57588612; called by muse, mutect2, varscan2
- SETD4 | c.552T>A p.F184L | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.137); catalogued as COSV59772534; called by muse, mutect2, varscan2
- SHOC1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 50/155 reads (32%) | catalogued as COSV59503156; called by muse, mutect2, varscan2
- SON | c.3970G>C p.E1324Q | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.123); catalogued as COSV51661532; called by muse, mutect2, varscan2
- SUOX | c.31A>G p.R11G | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV57189068; called by muse, mutect2, varscan2
- SYNE1 | c.4178C>T p.A1393V (on ENST00000367255 / NM_182961.4; = p.A1400V on NM_033071.3) | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV55010688; called by muse, mutect2, varscan2
- TAF1A | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100600931, COSV61918853; called by muse, mutect2, varscan2
- THAP5 | c.646C>A p.H216N (on ENST00000415914 / NM_001130475.3; = p.H174N on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192004311, COSV50812300; called by muse, mutect2, varscan2
- TMEM179B | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV53669322; called by muse, mutect2, varscan2
- TMEM67 | c.2556G>A p.R852= | Splice Region (SNP) | VAF 28/124 reads (23%) | catalogued as COSV60040861; called by muse, mutect2, varscan2
- TMPRSS11D | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 107/395 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs370881465; called by muse, mutect2, varscan2
- TRHDE | c.1856T>A p.F619Y | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53849180; called by muse, mutect2, varscan2
- TTC37 | c.1332G>C p.Q444H | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV62455269; called by muse, mutect2, varscan2
- TUBGCP3 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1443838723, COSV56187804; called by muse, mutect2, varscan2
- USP9X | c.7151C>A p.A2384E | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61070711, COSV61072555; called by muse, mutect2, varscan2
- VRK3 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV57466200; called by muse, mutect2, varscan2
- WDR19 | c.637T>A p.F213I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56466360; called by muse, mutect2, varscan2
- WDR81 | c.3944A>T p.Y1315F (on ENST00000409644 / NM_001163809.2; = p.Y264F on NM_152348.4) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58484293; called by muse, mutect2, varscan2
- ZDHHC16 | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 94/401 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59135785; called by muse, mutect2, varscan2
- ZDHHC16 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 95/407 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV59135794; called by muse, mutect2, varscan2
- ZNF492 | c.1492A>T p.I498F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV71762067; called by muse, mutect2, varscan2
- ZNF561 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV57177994; called by muse, mutect2, varscan2
- ZNF677 | c.1599C>G p.H533Q | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100448122, COSV61720541; called by muse, mutect2, varscan2
- ATF7IP | c.3612del p.E1204Dfs*60 | Frame Shift Del (DEL) | VAF 20/137 reads (15%) | called by mutect2, pindel, varscan2
- BLMH | c.961-9_963del p.X321_splice | Splice Site (DEL) | VAF 127/433 reads (29%) | called by mutect2, pindel, varscan2
- BSDC1 | c.712_714delinsA p.E238Sfs*13 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by pindel, varscan2*
- CACYBP | c.528del p.E177Rfs*15 | Frame Shift Del (DEL) | VAF 25/118 reads (21%) | called by mutect2, pindel, varscan2
- COPS7B | c.22_45del p.S8_F15del | In Frame Del (DEL) | VAF 25/138 reads (18%) | called by mutect2, pindel
- GRAMD1C | c.847del p.T283Lfs*6 | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.3230dup p.Q1078Afs*25 | Frame Shift Ins (INS) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- KAT6A | c.2365_2398del p.E789Kfs*10 | Frame Shift Del (DEL) | VAF 44/262 reads (17%) | called by mutect2, pindel
- LARP1 | c.3060_3067del p.E1022Pfs*8 (on ENST00000518297 / NM_033551.3; = p.E945Pfs*8 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 130/327 reads (40%) | called by mutect2, pindel, varscan2
- MMADHC | c.438_459del p.E147Qfs*15 | Frame Shift Del (DEL) | VAF 22/250 reads (9%) | called by mutect2, pindel
- MMP11 | c.254del p.P85Hfs*5 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- NXPH3 | c.607del p.H203Tfs*121 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | called by mutect2, pindel, varscan2
- OR8G2P | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 136/479 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- OTUD4 | c.790del p.W264Gfs*2 (on ENST00000447906 / NM_001366057.1; = p.W199Gfs*2 on NM_001102653.1) | Frame Shift Del (DEL) | VAF 78/271 reads (29%) | called by mutect2, varscan2
- PEX1 | c.2167_2169del p.V723del | In Frame Del (DEL) | VAF 37/110 reads (34%) | called by mutect2, pindel, varscan2
- RABGGTA | c.73_75del p.L25del | In Frame Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- SLC16A14 | c.1265del p.F422Sfs*3 | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | called by mutect2, pindel, varscan2
- SUZ12 | c.991dup p.R331Kfs*9 | Frame Shift Ins (INS) | VAF 78/312 reads (25%) | called by mutect2, pindel, varscan2
- TRMT13 | c.1182del p.N394Kfs*34 | Frame Shift Del (DEL) | VAF 60/264 reads (23%) | called by mutect2, pindel, varscan2
- C6orf58 | c.429G>A p.A143= | Silent (SNP) | VAF 59/237 reads (25%) | catalogued as rs760381981, COSV61666712; called by muse, mutect2, varscan2
- CCNDBP1 | c.343A>C p.R115= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV53041536; called by muse, mutect2, varscan2
- CLIP1 | c.1557A>C p.L519= (on ENST00000620786 / NM_001247997.1; = p.L508= on NM_002956.2) | Silent (SNP) | VAF 87/346 reads (25%) | catalogued as COSV56803330; called by muse, mutect2, varscan2
- CPNE1 | c.642T>C p.D214= (on ENST00000352393; = p.D219= on NM_003915.5) | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV58292553; called by muse, mutect2, varscan2
- CPXM1 | c.1935G>A p.V645= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV66045727; called by muse, mutect2, varscan2
- CSMD3 | c.5415A>G p.V1805= (on ENST00000297405 / NM_001363185.1; = p.V1701= on NM_052900.3) | Silent (SNP) | VAF 71/245 reads (29%) | catalogued as rs1443416729, COSV52210992; called by muse, mutect2, varscan2
- DHRS4L2 | c.210C>T p.D70= | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as COSV58730005; called by muse, mutect2, varscan2
- DRD3 | c.678A>T p.R226= | Silent (SNP) | VAF 130/419 reads (31%) | catalogued as COSV55680751; called by muse, mutect2, varscan2
- FASTKD2 | c.1398C>A p.L466= | Silent (SNP) | VAF 67/234 reads (29%) | catalogued as COSV52698803; called by muse, mutect2, varscan2
- FYB1 | c.216A>G p.E72= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as COSV60948926; called by muse, mutect2, varscan2
- GSDME | c.1284A>G p.V428= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs779992896, COSV61652012; called by muse, mutect2, varscan2
- H3-5 | c.174C>T p.T58= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as rs957089604, COSV61187501; called by muse, mutect2, varscan2
- ITSN2 | c.193T>C p.L65= | Silent (SNP) | VAF 101/357 reads (28%) | catalogued as COSV61948865; called by muse, mutect2, varscan2
- KMT2A | c.3918G>A p.P1306= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs781862991, COSV63287409; called by muse, mutect2, varscan2
- LACTB | c.826C>A p.R276= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV56056171; called by muse, mutect2, varscan2
- LAMC3 | c.1131G>A p.R377= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1352416564, COSV63092434; called by muse, mutect2, varscan2
- LRRC8B | c.771A>G p.V257= | Silent (SNP) | VAF 68/214 reads (32%) | catalogued as rs749264836, COSV58375544; called by muse, mutect2, varscan2
- LRRIQ4 | c.1635A>G p.K545= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV52981326; called by muse, mutect2, varscan2
- MTREX | c.2595T>A p.T865= | Silent (SNP) | VAF 65/370 reads (18%) | catalogued as COSV57926876; called by muse, mutect2, varscan2
- MUC6 | c.5187C>T p.T1729= | Silent (SNP) | VAF 124/949 reads (13%) | catalogued as COSV70143465; called by muse, varscan2
- MYO5C | c.3159T>A p.T1053= | Silent (SNP) | VAF 76/282 reads (27%) | catalogued as COSV55907744; called by muse, mutect2, varscan2
- NCOA2 | c.3039A>G p.E1013= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV51220262; called by muse, mutect2, varscan2
- NECTIN3 | c.735T>A p.T245= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as COSV60551882; called by muse, mutect2, varscan2
- NFIX | c.1116C>T p.P372= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV62178174; called by muse, mutect2, varscan2
- NID2 | c.390C>G p.P130= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV53497397, COSV53497910; called by muse, varscan2
- PPP1R10 | c.2541C>T p.P847= | Silent (SNP) | VAF 65/205 reads (32%) | catalogued as COSV64739614; called by muse, mutect2, varscan2
- SCARA3 | c.168G>T p.R56= | Silent (SNP) | VAF 14/278 reads (5%) | catalogued as COSV57270504; called by muse, mutect2
- SH2D3A | c.876C>T p.P292= | Silent (SNP) | VAF 34/506 reads (7%) | catalogued as COSV55586582; called by muse, mutect2
- TACR2 | c.900C>T p.T300= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as rs750804049, COSV64822409; called by muse, mutect2, varscan2
- TOP1MT | c.351C>T p.D117= | Silent (SNP) | VAF 54/232 reads (23%) | catalogued as COSV61318340; called by muse, varscan2
- VNN2 | c.1563G>A p.*521= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV58472902; called by muse, mutect2, varscan2
- DCUN1D1 | c.*2A>C | 3'UTR (SNP) | VAF 34/121 reads (28%) | catalogued as COSV99489873; called by muse, mutect2, varscan2
